Gene-level copy-number profile of tumor specimen TCGA-E7-A85H-01A from TCGA case TCGA-E7-A85H, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 64.3 years (23,497 days).
Specimen TCGA-E7-A85H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.4e018326-df18-4f87-a357-36c56877604d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-E7-A85H-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/abce8665-74ca-48be-878d-9e736596e270

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,109; copy number 2: 13,523; copy number 3: 24,091; copy number 4: 12,875; copy number 5: 3,992; copy number 6: 916; copy number 7: 604; copy number 8: 576; copy number 9: 27; copy number 10: 3; copy number 11: 41; copy number 19: 49.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-E7-A85H-01A-11D-A34T-01): tumor purity 0.74, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,300 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,649,151–172,666,876, 348 genes, copy number 7–8 (broad region; genes not listed).
- chr2:44,921,077–45,323,397, 19 genes, copy number 7: LINC01833, AC012354.9, AC012354.2, AC012354.7, AC012354.5, AC012354.8, AC012354.4, AC012354.3, AC012354.6, SIX3-AS1, SIX3, AC012354.1, KRTCAP2P1, SIX2, AC093702.1, LINC01121, AC093833.1, AC009236.2, AC009236.1.
- chr3:101,324,205–117,139,389, 207 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr3:118,004,819–122,639,047, 95 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr4:51,843,000–56,977,606, 111 genes, copy number 7 (broad region; genes not listed).
- chr6:19,143,695–21,232,404, 25 genes, copy number 7–9 (within-gene range 5–9): AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P.
- chr6:21,664,185–26,157,115, 92 genes, copy number 7–8 (broad region; genes not listed).
- chr7:66,606,738–68,036,917, 31 genes, copy number 7–10: RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS, TYW1, AC073089.1, MIR4650-1, SPDYE21, PMS2P4, Y_RNA, STAG3L4, AC006480.1, AC006480.2, MTATP6P21, MTCO3P41, AC005482.1, AC092648.1, AC092637.1.
- chr8:37,597,480–41,032,998, 84 genes, copy number 9–19 (broad region; genes not listed).
- chr8:60,185,412–63,234,911, 45 genes, copy number 8–11: CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3, AC068389.1, AC068389.2, CHD7, AC113143.1, AC113143.2, IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P.
- chr8:66,419,589–67,849,338, 33 genes, copy number 7: RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6.
- chr8:82,033,533–82,961,926, 1 gene, copy number 8 (within-gene range 6–8): AC060765.2.
- chr8:82,514,568–83,408,900, 7 genes, copy number 8: AC060765.1, AC105031.2, AC105031.1, AC090095.1, AC090132.1, AC090132.2, LINC01419.
- chr8:84,182,787–87,615,219, 58 genes, copy number 8 (within-gene range 3–8): RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1.
- chr8:100,831,728–101,669,726, 29 genes, copy number 7: RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1.
- chr9:6,195,934–7,961,224, 31 genes, copy number 7: GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1, KDM4C, PRELID3BP11, SNRPEP2, ACTG1P14, AL513412.1, AL161443.1, AL157703.1, RPL4P5, PPIAP33, AL354694.1, DMAC1, AL135923.2, AL135923.1.
- chr9:10,631,750–12,300,451, 12 genes, copy number 7: AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P.
- chr13:83,877,205–84,069,408, 6 genes, copy number 8: SLITRK1, AL355481.1, VENTXP2, AL590681.1, UBE2D3P4, AL445604.1.
- chr15:26,115,726–26,477,840, 4 genes, copy number 9 (within-gene range 5–9): LINC00929, AC012060.1, LINC02248, AC009878.2.
- chr15:26,557,598–26,557,937, 1 gene, copy number 9: AC009878.1.
- chr17:26,981,694–28,223,735, 47 genes, copy number 8: AC069061.1, AC069061.2, PDLIM1P3, GTF2IP6, VN1R71P, TUFMP1, AC129926.2, AC129926.1, RPL34P31, RPS16P8, AC026254.1, MIR4522, WSB1, AC026254.2, SYPL1P2, AC090615.1, TBC1D3P5, KSR1, AC069366.2, AC069366.1, ITM2BP1, AC015688.4, AC015688.6, LGALS9, NOS2P1, AC015688.3, AC015688.5, CPDP1, AC015688.2, AC015688.1, AC130289.1, AC130289.2, LGALS9DP, NOS2, AC005697.1, AC005697.2, LYRM9, LINC01992, AC005697.3, AC090287.1, AC090287.2, SNORA70, NLK, Vault, RPS29P22, AC061975.8, AC061975.7.
- chr17:41,334,632–41,481,140, 13 genes, copy number 7 (within-gene range 3–7): AC003958.1, KRT33A, KRT33B, KRT34, KRT31, AC003958.2, KRT41P, KRT37, KRT38, KRT43P, KRT32, RNU2-32P, KRT35.
- chr20:55,607,852–55,744,938, 1 gene, copy number 7: AL109829.1.

Autosomal genes at a single copy (total copy number 1): 1,941. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
